Somatic mutation profile of tumor specimen 855256a7-e41e-4158-b02f-ba61a9 (aliquot 855256a7-e41e-4158-b02f-ba61a9_D6_1) from CPTAC case 11BR018, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 54.4 years (19,862 days).
Specimen 855256a7-e41e-4158-b02f-ba61a9: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c65d2bfe-6e92-4c30-9a18-ff8194cbb616.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ba088f32-97f7-446a-9b7b-a804d2 (Blood Derived Normal), aliquot ba088f32-97f7-446a-9b7b-a804d2_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6955954b-6aa0-48ab-98f7-d0f4be47d871

The open-access MAF lists 87 somatic variants for this specimen: 49 protein-altering or splice-affecting, 25 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 25, Intron 6, Nonsense Mutation 5, 3'Flank 2, RNA 2, 5'UTR 2, Splice Region 2, Frame Shift Del 1, 3'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 79/406 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55733498, COSV99932866; called by muse, mutect2, varscan2
- PIK3CA | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 34/187 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.285); catalogued as rs1064793732, CM126690, COSV55881636, COSV55977337; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DAB1 | c.1639G>C p.E547Q (on ENST00000371231; = p.E514Q on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.801); catalogued as COSV64690695; called by muse, mutect2
- DNAH10 | c.6779A>G p.E2260G (on ENST00000409039; = p.E2199G on NM_207437.3) | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1468550497; called by muse, mutect2
- DSG1 | c.673C>G p.L225V | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57136149; called by muse, mutect2, varscan2
- EEF1A1 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.609); catalogued as COSV58549416, COSV58550657; called by muse, mutect2, varscan2
- FAT3 | c.5653C>T p.Q1885* | Nonsense Mutation (SNP) | VAF 26/510 reads (5%) | catalogued as COSV53084246; called by muse, mutect2
- FGD1 | c.2597G>A p.R866H | Missense Mutation (SNP) | VAF 39/258 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.258); catalogued as COSV64308489; called by muse, mutect2, varscan2
- LAMB2 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 72/603 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs773490060; called by muse, mutect2, varscan2
- MAP3K15 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1203670528; called by muse, mutect2
- MKI67 | c.1115G>C p.R372T | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.118); catalogued as COSV64076780; called by muse, mutect2
- MRPL45 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs767927015; called by muse, mutect2
- NEO1 | c.1673C>T p.T558M | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as rs376506948; called by muse, mutect2
- NHLH1 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.216); catalogued as rs757371187; called by muse, mutect2, varscan2
- PDCD11 | c.1849G>C p.E617Q | Missense Mutation (SNP) | VAF 20/253 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.11); catalogued as COSV100874244; called by muse, mutect2
- PDIA4 | c.562G>C p.D188H | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV53724556; called by muse, mutect2
- PTPN21 | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 29/428 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60851498; called by muse, mutect2
- RAG1 | c.430A>G p.K144E | Missense Mutation (SNP) | VAF 10/356 reads (3%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.106); catalogued as rs1341918341; called by muse, mutect2
- RTL5 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.055); catalogued as rs777354507; called by muse, mutect2, varscan2
- SPTBN2 | c.6869G>A p.R2290Q | Missense Mutation (SNP) | VAF 48/549 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.403); catalogued as rs200100829, COSV100019430; called by muse, mutect2
- TBX4 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 51/793 reads (6%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.992); catalogued as rs759150888, COSV99540693; called by muse, mutect2
- TLN2 | c.1573C>G p.L525V | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1369221722; called by muse, mutect2, varscan2
- TNFRSF9 | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs982877326; called by muse, mutect2, varscan2
- UCMA | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs753490238, COSV66321951; called by muse, varscan2
- WDR26 | c.566C>T p.S189L (on ENST00000414423 / NM_001379403.1; = p.S89L on NM_025160.7) | Missense Mutation (SNP) | VAF 21/205 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs1558450796; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZFP28 | c.2584C>T p.P862S | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.031); catalogued as COSV56735820; called by muse, mutect2, varscan2
- ADPRS | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- ALG13 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 33/203 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- BACH2 | c.1548G>T p.R516S | Missense Mutation (SNP) | VAF 21/223 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.815); called by muse, mutect2
- CALML4 | c.407T>C p.V136A | Missense Mutation (SNP) | VAF 33/252 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL11A1 | c.4297C>T p.P1433S | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CPD | c.3819C>G p.V1273= | Splice Region (SNP) | VAF 20/95 reads (21%) | called by muse, mutect2, varscan2
- CUL4B | c.2493+7C>T | Splice Region (SNP) | VAF 11/230 reads (5%) | called by muse, mutect2
- DOCK1 | c.3325G>C p.D1109H | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FAT1 | c.2828G>A p.G943E | Missense Mutation (SNP) | VAF 24/428 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPS2 | c.241del p.E81Kfs*28 | Frame Shift Del (DEL) | VAF 30/199 reads (15%) | called by mutect2, pindel, varscan2
- MICALL2 | c.1190C>T p.S397F | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- MSC | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- NLN | c.1610G>A p.W537* | Nonsense Mutation (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- PCNX1 | c.3893C>A p.T1298K | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2
- PDCD11 | c.1105G>T p.D369Y | Missense Mutation (SNP) | VAF 38/391 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.429); called by mutect2, varscan2
- PPP6R2 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.783); called by muse, mutect2
- RLIM | c.886C>T p.Q296* | Nonsense Mutation (SNP) | VAF 25/308 reads (8%) | called by muse, mutect2
- THRAP3 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 36/209 reads (17%) | called by muse, mutect2, varscan2
- TMEM94 | c.2281C>T p.Q761* | Nonsense Mutation (SNP) | VAF 60/620 reads (10%) | called by muse, mutect2
- UNC13C | c.1304C>G p.S435C | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- WT1 | c.1052G>A p.R351K | Missense Mutation (SNP) | VAF 16/432 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.646); called by muse, mutect2
- ZFHX4 | c.5911C>A p.Q1971K | Missense Mutation (SNP) | VAF 8/201 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.037); called by muse, mutect2
- ZFPM2 | c.2480A>G p.D827G | Missense Mutation (SNP) | VAF 32/686 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ADAMTSL2 | c.1905G>A p.S635= | Silent (SNP) | VAF 75/401 reads (19%) | called by muse, mutect2, varscan2
- AFF3 | c.1272C>T p.S424= | Silent (SNP) | VAF 34/188 reads (18%) | catalogued as rs894669084; called by muse, varscan2
- CEACAM18 | c.663G>C p.L221= | Silent (SNP) | VAF 16/226 reads (7%) | called by muse, mutect2
- CRTAP | c.300C>T p.L100= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as rs1299517834, COSV58014783; called by muse, mutect2, varscan2
- E4F1 | c.129C>G p.L43= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV57039228; called by muse, mutect2
- ETAA1 | c.639G>A p.K213= | Silent (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2, varscan2
- FNDC10 | c.378C>T p.L126= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- HARS2 | c.1395C>T p.V465= | Silent (SNP) | VAF 22/456 reads (5%) | catalogued as COSV51227578; called by muse, mutect2
- HDAC3 | c.264C>T p.F88= | Silent (SNP) | VAF 12/128 reads (9%) | called by muse, mutect2
- HEATR5B | c.5478C>T p.G1826= | Silent (SNP) | VAF 48/302 reads (16%) | catalogued as rs772765602; called by muse, mutect2, varscan2
- LRRK1 | c.5043C>T p.I1681= | Silent (SNP) | VAF 82/585 reads (14%) | catalogued as rs758003738; called by muse, mutect2, varscan2
- MYH15 | c.3612G>A p.L1204= | Silent (SNP) | VAF 37/278 reads (13%) | catalogued as rs1298457917; called by muse, mutect2, varscan2
- PALD1 | c.1788G>A p.L596= | Silent (SNP) | VAF 22/234 reads (9%) | catalogued as rs201455976, COSV54978833; called by muse, mutect2
- PKHD1 | c.6267G>A p.P2089= | Silent (SNP) | VAF 23/427 reads (5%) | catalogued as rs1399100600; called by muse, mutect2
- PLS3 | c.180C>T p.L60= | Silent (SNP) | VAF 11/169 reads (7%) | catalogued as COSV56778267; called by muse, mutect2
- POM121 | c.3399G>A p.Q1133= (on ENST00000434423; = p.Q868= on NM_172020.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/606 reads (6%) | catalogued as rs782121689; called by muse, mutect2
- PSG2 | c.327C>T p.I109= | Silent (SNP) | VAF 26/406 reads (6%) | called by muse, mutect2
- TCHH | c.762G>A p.R254= | Silent (SNP) | VAF 22/248 reads (9%) | catalogued as rs1348776174; called by muse, mutect2
- TRIM44 | c.270G>A p.E90= | Silent (SNP) | VAF 22/245 reads (9%) | called by muse, mutect2
- TTN | c.26004G>C p.V8668= (on ENST00000591111; = p.V7741= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/194 reads (13%) | catalogued as COSV60412613; called by muse, mutect2, varscan2
- USP39 | c.1200C>T p.L400= | Silent (SNP) | VAF 13/144 reads (9%) | catalogued as rs1463927382; called by muse, mutect2
- VPS9D1 | c.1419G>C p.L473= | Silent (SNP) | VAF 4/66 reads (6%) | called by muse, mutect2
- WASHC2C | c.1389C>T p.F463= | Silent (SNP) | VAF 56/332 reads (17%) | catalogued as COSV60490092; called by muse, mutect2, varscan2
- ZNF385D | c.150C>T p.F50= | Silent (SNP) | VAF 17/174 reads (10%) | called by muse, mutect2
- ZNF792 | c.1731C>G p.L577= | Silent (SNP) | VAF 18/404 reads (4%) | called by muse, mutect2
- AC136604.1 | n.432G>A | RNA (SNP) | VAF 70/476 reads (15%) | called by muse, mutect2, varscan2
- ANXA8L1 | c.207+76C>T | Intron (SNP) | VAF 24/372 reads (6%) | called by muse, mutect2
- ERGIC3 | chr20:35560608 C>T | 3'Flank (SNP) | VAF 25/178 reads (14%) | catalogued as rs1256064322; called by muse, mutect2, varscan2
- FGFR1 | c.-88-3593C>T | Intron (SNP) | VAF 33/323 reads (10%) | called by muse, mutect2, varscan2
- IGHV3-38 | c.-28G>A | 5'UTR (SNP) | VAF 12/265 reads (5%) | called by muse, mutect2
- LINC02312 | n.627G>A | RNA (SNP) | VAF 55/417 reads (13%) | catalogued as rs183798919; called by muse, mutect2, varscan2
- MAP1A | c.-29G>A | 5'UTR (SNP) | VAF 52/334 reads (16%) | catalogued as rs1242627323; called by muse, mutect2, varscan2
- MYL3 | chr3:46834010 G>A | 3'Flank (SNP) | VAF 26/180 reads (14%) | catalogued as rs1189421585, COSV70134013; called by muse, mutect2, varscan2
- NIBAN3 | c.1843+44G>C | Intron (SNP) | VAF 31/206 reads (15%) | called by muse, mutect2, varscan2
- RAD51D | c.*308G>T | 3'UTR (SNP) | VAF 5/90 reads (6%) | called by muse, mutect2
- ROGDI | c.433-25G>C | Intron (SNP) | VAF 9/114 reads (8%) | called by muse, mutect2
- SLC9A6 | c.429+34C>T | Intron (SNP) | VAF 37/298 reads (12%) | called by muse, mutect2, varscan2
- VEZT | c.37-7961G>C | Intron (SNP) | VAF 10/166 reads (6%) | called by muse, mutect2
